TCGA case TCGA-04-1332 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b46263ab-c3ca-4fda-a895-74c7e6e6fe22

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 1,247 days (3.4 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,786 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel + Topotecan; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 179 days; Number of cycles: 4; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 424 days (1.2 years); Days to treatment end: 606 days (1.7 years); Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 971 days (2.7 years); Days to treatment end: 1,063 days (2.9 years); Number of cycles: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,094 days (3.0 years); Days to treatment end: 1,155 days (3.2 years); Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,155 days (3.2 years); Days to treatment end: 1,216 days (3.3 years); Number of cycles: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Number of cycles: 7.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Number of cycles: 7.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 71.7 years (26,179 days); Days to diagnosis: 393 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 393 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 393 days (1.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,247 days (3.4 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-04-1332-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 89; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 52.
  Slide TCGA-04-1332-01A-01-TS1: Section location: Top; Percent tumor cells: 8; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 89.
- Sample TCGA-04-1332-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Topotecan/Carboplatin.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 6: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxol/Carboplatin.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-04-1332-01): tumor purity 0.5, ploidy 2.76, whole-genome doublings 1 (call status: legacy_call).
